Gene-level copy-number profile of tumor specimen TCGA-DD-AACV-01A from TCGA case TCGA-DD-AACV, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 53.8 years (19,660 days).
Specimen TCGA-DD-AACV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.2209cd28-8bed-4ad8-b42e-b67a21f5b43a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AACV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5f987873-276d-4ebb-a544-8e73a7443b08

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 13,288; copy number 2: 43,674; copy number 3: 1,881; copy number 4: 781; copy number 5: 73; copy number 6: 1; copy number 7: 15; copy number 8: 107.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AACV-01A-11D-A40Q-01): tumor purity 0.99, ploidy 1.85, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 196 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:20,173,632–21,014,822, 63 genes, copy number 5 (broad region; genes not listed).
- chr14:21,023,314–21,036,276, 5 genes, copy number 5: MIR6717, TPPP2, AL161668.4, AL161668.2, RNASE13.
- chr19:27,638,483–28,125,430, 15 genes, copy number 7: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1.
- chr19:29,205,320–29,233,385, 5 genes, copy number 5: UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P.
- chr19:29,838,532–29,841,818, 1 gene, copy number 6: AC008798.2.
- chr19:39,236,433–41,027,720, 107 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,901. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
